Gene-level copy-number profile of tumor specimen HCM-CSHL-0817-C22-01A from HCMI case HCM-CSHL-0817-C22, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage IIIB; Tumor grade: GX; Age at diagnosis: 75.3 years (27,513 days).
Specimen HCM-CSHL-0817-C22-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a4b3ad27-f5d4-4c68-95b9-1c4eb7754cb0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0817-C22-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/d2cde3b9-2f4e-4f3d-9e92-a594eddefbf0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 11,184; copy number 2: 45,430; copy number 3: 1,774.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:10,992,186–11,771,350, 12 genes: SLC6A1, SLC6A1-AS1, HRH1, AC083855.2, CHCHD4P4, ATG7, AC083855.1, AC026185.1, AC022001.1, VGLL4, AC022001.2, AC022001.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 11,184. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
